Somatic mutation profile of tumor specimen HCM-CSHL-0381-C20-86A (aliquot HCM-CSHL-0381-C20-86A-01D-A937-36) from HCMI case HCM-CSHL-0381-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 46.8 years (17,107 days).
Specimen HCM-CSHL-0381-C20-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d1cc5e1-5df4-42ea-a94d-9a02a7afa4d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0381-C20-10A (Blood Derived Normal), aliquot HCM-CSHL-0381-C20-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9733aa04-4ecb-453d-b07c-9d69499ac27a

The open-access MAF lists 112 somatic variants for this specimen: 85 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 24, Frame Shift Del 10, Nonsense Mutation 7, In Frame Del 4, 3'UTR 2, Splice Region 2, Frame Shift Ins 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 239/489 reads (49%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 192/420 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 229/229 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADCY2 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 195/436 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs769674129, COSV57864636; called by muse, mutect2, varscan2
- AGRN | c.4319C>T p.P1440L | Missense Mutation (SNP) | VAF 230/452 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.13); catalogued as rs1013476257; called by muse, mutect2, varscan2
- AHNAK2 | c.2662G>A p.A888T | Missense Mutation (SNP) | VAF 338/343 reads (99%) | SIFT tolerated (0.41); PolyPhen benign (0.292); catalogued as rs772936043, COSV100317494; called by muse, mutect2, varscan2
- AMDHD2 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 238/469 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.196); catalogued as rs763752753; called by muse, mutect2, varscan2
- AOC3 | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 277/552 reads (50%) | catalogued as rs758238458, COSV57732549; called by muse, mutect2, varscan2
- APC | c.4304del p.R1435Kfs*38 | Frame Shift Del (DEL) | VAF 176/399 reads (44%) | catalogued as COSV57331063, COSV57332751; called by mutect2, pindel, varscan2
- ARHGAP33 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 242/454 reads (53%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.677); catalogued as rs777134004; called by muse, mutect2, varscan2
- B2M | c.45_48del p.S16Afs*27 | Frame Shift Del (DEL) | VAF 189/197 reads (96%) | catalogued as COSV62562863; called by mutect2, pindel, varscan2
- COL21A1 | c.1216T>A p.L406M | Missense Mutation (SNP) | VAF 199/402 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.855); catalogued as COSV55157436; called by muse, mutect2, varscan2
- CPN2 | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 301/546 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs1416554747; called by muse, mutect2, varscan2
- DEFB108B | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 200/548 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.698); catalogued as rs151229532; called by muse, mutect2
- DMXL1 | c.4855C>T p.R1619C | Missense Mutation (SNP) | VAF 156/346 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201096718, COSV100224530; called by muse, mutect2, varscan2
- GRM6 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 276/584 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs1193992490; called by muse, mutect2
- H2BC18 | c.73_75del p.K25del | In Frame Del (DEL) | VAF 186/400 reads (47%) | catalogued as rs782079686; called by pindel, varscan2
- HS3ST3A1 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 152/328 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs779968068; called by muse, varscan2
- HS3ST3B1 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 59/96 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as rs1220496585; called by muse, mutect2, varscan2
- KCND1 | c.389A>T p.D130V | Missense Mutation (SNP) | VAF 323/625 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV54414730; called by muse, mutect2, varscan2
- KCNIP1 | c.358G>A p.E120K (on ENST00000411494 / NM_001034837.3; = p.E109K on NM_014592.4) | Missense Mutation (SNP) | VAF 127/249 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.072); catalogued as rs550125684, COSV61089559; called by muse, mutect2, varscan2
- KIAA1586 | c.1828A>G p.I610V | Missense Mutation (SNP) | VAF 153/311 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.894); catalogued as rs776920348; called by muse, mutect2, varscan2
- LAMA3 | c.4546G>A p.A1516T | Missense Mutation (SNP) | VAF 191/191 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs776672532; called by muse, mutect2, varscan2
- LAMB2 | c.5081G>A p.R1694H | Missense Mutation (SNP) | VAF 173/376 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.893); catalogued as rs758687310; called by muse, mutect2, varscan2
- LRRIQ3 | c.699A>T p.K233N | Missense Mutation (SNP) | VAF 131/262 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV63043534; called by muse, mutect2
- LRRIQ3 | c.697A>T p.K233* | Nonsense Mutation (SNP) | VAF 132/266 reads (50%) | catalogued as rs376287445; called by muse, mutect2
- MAP2 | c.3599C>A p.P1200Q | Missense Mutation (SNP) | VAF 147/302 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52291213; called by muse, mutect2, varscan2
- MMRN2 | c.2068G>A p.A690T | Missense Mutation (SNP) | VAF 334/667 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV64400404; called by muse, mutect2, varscan2
- NCAPG | c.1105G>C p.D369H | Missense Mutation (SNP) | VAF 145/300 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV52269779; called by muse, mutect2, varscan2
- OR13D1 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 248/548 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV59513712; called by muse, mutect2
- OXTR | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 240/521 reads (46%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); catalogued as rs756453502; called by muse, mutect2, varscan2
- POMZP3 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 138/508 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.818); catalogued as rs779256643; called by muse, mutect2, varscan2
- SCRIB | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 389/1199 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs760633347, COSV100254332; called by muse, mutect2, varscan2
- TBC1D2 | c.1316G>T p.R439L | Missense Mutation (SNP) | VAF 217/429 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV59786021; called by muse, mutect2, varscan2
- UMODL1 | c.2270C>T p.S757L (on ENST00000408910 / NM_001004416.2; = p.S885L on NM_173568.3) | Missense Mutation (SNP) | VAF 258/497 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs765973844, COSV68571659; called by muse, mutect2, varscan2
- UTRN | c.8462C>G p.S2821C | Missense Mutation (SNP) | VAF 155/357 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV104422959; called by muse, mutect2, varscan2
- ZNF581 | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 249/537 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as rs1280303701; called by muse, mutect2, varscan2
- AGTR1 | c.997A>T p.K333* | Nonsense Mutation (SNP) | VAF 146/362 reads (40%) | called by muse, varscan2
- AGTR1 | c.998A>T p.K333I | Missense Mutation (SNP) | VAF 148/363 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, varscan2
- CCDC157 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 289/289 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CLTC | c.1521dup p.V508Sfs*33 | Frame Shift Ins (INS) | VAF 93/259 reads (36%) | called by mutect2, pindel, varscan2
- CNNM2 | c.2446T>G p.L816V | Missense Mutation (SNP) | VAF 181/385 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CTNND1 | c.2227A>C p.N743H (on ENST00000399050 / NM_001085458.2; = p.N737H on NM_001331.3) | Missense Mutation (SNP) | VAF 134/309 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CWF19L1 | c.1546del p.E516Kfs*37 | Frame Shift Del (DEL) | VAF 213/546 reads (39%) | called by mutect2, pindel, varscan2
- DAB2 | c.2143_2151del p.P715_P717del | In Frame Del (DEL) | VAF 70/233 reads (30%) | called by pindel, varscan2*
- DTNB | c.899_902del p.S300Mfs*33 | Frame Shift Del (DEL) | VAF 107/236 reads (45%) | called by mutect2, pindel, varscan2
- EEF2K | c.695_701del p.I232Tfs*20 | Frame Shift Del (DEL) | VAF 179/466 reads (38%) | called by mutect2, pindel, varscan2
- FAM24B | c.209G>T p.C70F | Missense Mutation (SNP) | VAF 262/484 reads (54%) | SIFT tolerated (0.61); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- FAT2 | c.4250A>C p.N1417T | Missense Mutation (SNP) | VAF 282/625 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAT4 | c.1616del p.G539Afs*12 | Frame Shift Del (DEL) | VAF 32/229 reads (14%) | called by mutect2, pindel, varscan2
- FBN2 | c.2519G>A p.G840E | Missense Mutation (SNP) | VAF 185/392 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGF6 | c.460_477del p.Q154_F159del | In Frame Del (DEL) | VAF 106/312 reads (34%) | called by mutect2, pindel, varscan2
- FREM2 | c.8375_8378del p.P2792Hfs*21 | Frame Shift Del (DEL) | VAF 126/301 reads (42%) | called by mutect2, pindel, varscan2
- GOLGA6L6 | c.336G>T p.E112D | Missense Mutation (SNP) | VAF 66/96 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- HMGN5 | c.798T>A p.D266E | Missense Mutation (SNP) | VAF 128/301 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGA11 | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 216/216 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC25 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 272/558 reads (49%) | called by muse, mutect2, varscan2
- MAP3K5 | c.4047_4055del p.K1350_L1352del | In Frame Del (DEL) | VAF 93/261 reads (36%) | called by mutect2, pindel, varscan2
- MERTK | c.2973del p.S992Qfs*7 | Frame Shift Del (DEL) | VAF 126/347 reads (36%) | called by mutect2, pindel, varscan2
- MPDZ | c.905T>G p.I302S | Missense Mutation (SNP) | VAF 177/416 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MSX2 | c.378A>T p.P126= | Splice Region (SNP) | VAF 177/329 reads (54%) | called by muse, mutect2, varscan2
- NLGN4X | c.2206C>T p.Q736* | Nonsense Mutation (SNP) | VAF 227/503 reads (45%) | called by muse, mutect2, varscan2
- NOP14 | c.778C>G p.L260V | Missense Mutation (SNP) | VAF 161/306 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR5F1 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 134/308 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- PDGFC | c.180C>A p.S60R | Missense Mutation (SNP) | VAF 193/238 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PFDN2 | c.10A>G p.N4D | Missense Mutation (SNP) | VAF 232/511 reads (45%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- PITRM1 | c.2670G>T p.M890I | Missense Mutation (SNP) | VAF 163/337 reads (48%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RNF128 | c.225_256del p.Y75* | Frame Shift Del (DEL) | VAF 162/545 reads (30%) | called by mutect2, pindel, varscan2
- RPRD1B | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 134/426 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- SASH1 | c.863G>A p.G288D | Missense Mutation (SNP) | VAF 138/300 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- SF1 | c.452A>C p.N151T | Missense Mutation (SNP) | VAF 212/212 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC7A13 | c.517T>G p.F173V | Missense Mutation (SNP) | VAF 279/816 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- STK38 | c.371del p.D124Vfs*18 | Frame Shift Del (DEL) | VAF 141/360 reads (39%) | called by mutect2, pindel, varscan2
- SULF2 | c.1226G>T p.R409L | Missense Mutation (SNP) | VAF 48/818 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SYNE1 | c.21014T>C p.I7005T (on ENST00000367255 / NM_182961.4; = p.I6934T on NM_033071.3) | Missense Mutation (SNP) | VAF 108/329 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- TCF7L2 | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 211/419 reads (50%) | called by muse, mutect2, varscan2
- TG | c.3273G>T p.Q1091H | Missense Mutation (SNP) | VAF 185/694 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- THBS3 | c.2780T>C p.I927T | Missense Mutation (SNP) | VAF 202/432 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TRPC3 | c.2176A>G p.I726V (on ENST00000379645 / NM_001366479.2; = p.I653V on NM_003305.2) | Missense Mutation (SNP) | VAF 174/211 reads (82%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TUT1 | c.45dup p.F16Vfs*17 | Frame Shift Ins (INS) | VAF 177/380 reads (47%) | called by mutect2, varscan2
- UBR5 | c.5279C>G p.T1760R | Missense Mutation (SNP) | VAF 211/665 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- VWF | c.6978G>C p.V2326= | Splice Region (SNP) | VAF 138/274 reads (50%) | called by muse, mutect2, varscan2
- ZNF101 | c.1081A>C p.S361R | Missense Mutation (SNP) | VAF 159/303 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ZNF37A | c.379T>A p.F127I | Missense Mutation (SNP) | VAF 23/361 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- ZNF429 | c.1151T>C p.L384P | Missense Mutation (SNP) | VAF 221/432 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AGAP5 | c.1146C>A p.S382= | Silent (SNP) | VAF 57/930 reads (6%) | called by muse, mutect2
- AGTR1 | c.996A>C p.T332= | Silent (SNP) | VAF 148/362 reads (41%) | called by muse, varscan2
- ARAP3 | c.2517C>T p.G839= | Silent (SNP) | VAF 334/713 reads (47%) | called by muse, mutect2, varscan2
- BBX | c.621C>A p.G207= | Silent (SNP) | VAF 143/304 reads (47%) | called by muse, mutect2, varscan2
- CASP3 | c.681C>T p.A227= | Silent (SNP) | VAF 205/235 reads (87%) | catalogued as rs977632962, COSV57725842; called by muse, mutect2, varscan2
- COL5A2 | c.4194C>A p.S1398= | Silent (SNP) | VAF 239/505 reads (47%) | called by muse, mutect2, varscan2
- COL5A2 | c.2043T>C p.G681= | Silent (SNP) | VAF 160/353 reads (45%) | catalogued as rs1553515128, COSV66408961; ClinVar: likely benign; called by muse, mutect2, varscan2
- DIP2A | c.1008G>A p.L336= | Silent (SNP) | VAF 257/524 reads (49%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.9252T>C p.T3084= | Silent (SNP) | VAF 117/269 reads (43%) | called by muse, mutect2, varscan2
- GAA | c.2658G>T p.V886= | Silent (SNP) | VAF 149/323 reads (46%) | catalogued as COSV100163451; called by muse, mutect2, varscan2
- GRM1 | c.2976G>A p.P992= | Silent (SNP) | VAF 264/529 reads (50%) | catalogued as rs200487711, COSV51124415, COSV51268729; called by muse, mutect2, varscan2
- GSTK1 | c.672C>G p.A224= | Silent (SNP) | VAF 189/363 reads (52%) | called by muse, mutect2, varscan2
- HOXC9 | c.270G>A p.T90= | Silent (SNP) | VAF 311/687 reads (45%) | catalogued as COSV57717066; called by muse, mutect2, varscan2
- MYO7B | c.2649G>A p.P883= | Silent (SNP) | VAF 191/390 reads (49%) | catalogued as rs201458881; called by muse, mutect2, varscan2
- NWD2 | c.4875C>T p.S1625= | Silent (SNP) | VAF 224/441 reads (51%) | called by muse, mutect2, varscan2
- OLFML2A | c.1044G>A p.V348= | Silent (SNP) | VAF 254/489 reads (52%) | catalogued as rs1488787045; called by muse, mutect2, varscan2
- OR12D2 | c.81G>A p.V27= | Silent (SNP) | VAF 338/701 reads (48%) | called by muse, mutect2, varscan2
- RPRD2 | c.2724T>G p.S908= | Silent (SNP) | VAF 238/492 reads (48%) | called by muse, mutect2, varscan2
- SMARCC1 | c.423C>T p.N141= | Silent (SNP) | VAF 112/295 reads (38%) | called by muse, mutect2, varscan2
- SPTA1 | c.4419G>A p.T1473= | Silent (SNP) | VAF 192/403 reads (48%) | catalogued as rs771135166; called by muse, mutect2, varscan2
- UFL1 | c.681C>T p.S227= | Silent (SNP) | VAF 159/345 reads (46%) | called by muse, mutect2, varscan2
- VSIG10L2 | c.1701C>T p.D567= | Silent (SNP) | VAF 382/382 reads (100%) | called by muse, mutect2, varscan2
- WASHC2C | c.2091C>T p.S697= | Silent (SNP) | VAF 96/416 reads (23%) | catalogued as rs577995300; called by muse, mutect2
- ZYG11B | c.1521A>G p.Q507= | Silent (SNP) | VAF 153/291 reads (53%) | called by muse, mutect2, varscan2
- COL6A2 | c.2462-2619C>T | Intron (SNP) | VAF 368/755 reads (49%) | catalogued as COSV56002080; called by muse, mutect2, varscan2
- CXCL11 | c.*379T>A | 3'UTR (SNP) | VAF 122/255 reads (48%) | called by muse, mutect2, varscan2
- FUT9 | c.*7917C>A | 3'UTR (SNP) | VAF 157/431 reads (36%) | called by muse, mutect2, varscan2
